Somatic mutation profile of tumor specimen 35a345a4-e954-4c81-ae3f-7797cd (aliquot 35a345a4-e954-4c81-ae3f-7797cd_D6) from CPTAC case 26OV009, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 35a345a4-e954-4c81-ae3f-7797cd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ebb2dd4-5931-4a1f-a864-4643d960e547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 266c4207-1a8e-4343-bf1f-3304d0 (Blood Derived Normal), aliquot 266c4207-1a8e-4343-bf1f-3304d0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/042ce187-6ebd-4693-a66e-99b500c4e7fd

The open-access MAF lists 78 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Intron 5, RNA 4, Splice Site 2, 5'Flank 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 205/240 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AC004997.1 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated, low confidence (0.68); catalogued as rs1263006101; called by muse, mutect2, varscan2
- AIDA | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.108); catalogued as rs1324714308; called by muse, mutect2, varscan2
- ARHGEF15 | c.1329C>A p.F443L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62724817, COSV62724859; called by muse, mutect2
- EVI5L | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 106/748 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as rs754933940, COSV54484856; called by muse, mutect2, varscan2
- FCHSD1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs767970731; called by muse, mutect2, varscan2
- GNL3L | c.1739T>C p.V580A | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60575594; called by muse, mutect2, varscan2
- KDR | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); catalogued as rs1269556567; called by muse, mutect2, varscan2
- MACF1 | c.18718G>A p.E6240K (on ENST00000372915; = p.E4285K on NM_012090.5) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as rs147673829; called by muse, mutect2, varscan2
- MIA2 | c.1545G>A p.E515= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as rs769364726, COSV54491250; called by muse, mutect2
- MON2 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs749679342, COSV54805234; called by muse, mutect2, varscan2
- MUC12 | c.15637G>A p.D5213N (on ENST00000379442; = p.D5070N on NM_001164462.1) | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.24); catalogued as rs1055007617; called by muse, mutect2, varscan2
- NAV2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1478456857, COSV62338307; called by muse, mutect2, varscan2
- OR2G6 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 265/689 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs368580506, COSV58575716; called by muse, mutect2, varscan2
- PCDHA2 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV65366485; called by muse, mutect2
- PLA2R1 | c.1834+1G>T p.X612_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as rs775745800; called by muse, mutect2, varscan2
- PLIN1 | c.598+1G>C p.X200_splice | Splice Site (SNP) | VAF 36/258 reads (14%) | catalogued as rs113218013; called by muse, mutect2, varscan2
- PSME1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs747357229, COSV52825363; called by muse, mutect2, varscan2
- RGS22 | c.3118G>C p.A1040P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV62662362, COSV62665214; called by muse, mutect2, varscan2
- RNLS | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59292469; called by muse, mutect2, varscan2
- SLC37A1 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs776042921, COSV61402324; called by muse, mutect2
- SYP | c.5T>G p.L2R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs200470034; called by muse, mutect2, varscan2
- TBXAS1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 102/557 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.072); catalogued as rs762726298, COSV54940935; called by muse, mutect2, varscan2
- TRDN | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV62126421; called by muse, mutect2, varscan2
- TTLL4 | c.3145A>C p.T1049P | Missense Mutation (SNP) | VAF 203/295 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as rs1477829142; called by muse, mutect2, varscan2
- TTN | c.85129C>G p.P28377A (on ENST00000591111; = p.P20953A on NM_003319.4) | Missense Mutation (SNP) | VAF 92/252 reads (37%) | PolyPhen possibly damaging (0.64); catalogued as COSV100624683, COSV60161421; called by muse, mutect2, varscan2
- WDFY4 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1185507966; called by muse, mutect2, varscan2
- ADAM20 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ADNP | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN2L | c.2228A>T p.K743M | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BIRC6 | c.4844T>G p.V1615G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1C | c.6578G>C p.R2193P (on ENST00000399634 / NM_001167625.1; = p.R2122P on NM_000719.7) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CCDC141 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2
- CNGA4 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- COL17A1 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- EML6 | c.526T>C p.F176L | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEPACAM | c.779G>T p.C260F | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA11 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- INPP5J | c.2818G>C p.G940R (on ENST00000331075 / NM_001284285.2; = p.G572R on NM_001002837.2) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- KLHL32 | c.1444C>A p.Q482K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGA | c.4775del p.P1592Lfs*2 | Frame Shift Del (DEL) | VAF 212/321 reads (66%) | called by mutect2, pindel, varscan2
- MUC4 | c.12886A>G p.S4296G (on ENST00000463781 / NM_018406.7; = p.S60G on NM_004532.6) | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OXER1 | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 205/554 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PRMT8 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPSA | c.507C>G p.H169Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SEMA3E | c.2130C>A p.Y710* | Nonsense Mutation (SNP) | VAF 66/340 reads (19%) | called by muse, mutect2, varscan2
- SERPINA3 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 225/514 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- SREBF2 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.77342C>T p.T25781I (on ENST00000591111; = p.T18357I on NM_003319.4) | Missense Mutation (SNP) | VAF 89/290 reads (31%) | PolyPhen benign (0.186); called by muse, varscan2
- UNC80 | c.4315A>C p.I1439L | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZC3H12B | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF521 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 22/739 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by muse, mutect2
- ANKRD22 | c.148C>A p.R50= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- COL8A1 | c.2121G>C p.L707= | Silent (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- DGKB | c.1755T>C p.N585= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- DISP2 | c.1539G>C p.T513= | Silent (SNP) | VAF 168/381 reads (44%) | catalogued as rs371928290; called by muse, mutect2, varscan2
- IGKV3-15 | c.282C>G p.T94= | Silent (SNP) | VAF 59/579 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.21549G>A p.A7183= | Silent (SNP) | VAF 66/595 reads (11%) | catalogued as rs750262458; called by muse, mutect2, varscan2
- NAV3 | c.1341C>T p.A447= | Silent (SNP) | VAF 55/175 reads (31%) | called by muse, mutect2, varscan2
- POGLUT2 | c.786C>T p.S262= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV65683313; called by muse, mutect2
- RB1CC1 | c.535C>T p.L179= | Silent (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- RGS13 | c.174C>T p.D58= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs768100083, COSV67346384; called by muse, varscan2
- SDHA | c.444C>T p.A148= | Silent (SNP) | VAF 75/257 reads (29%) | catalogued as rs367618662, COSV53771002; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A19 | c.897C>T p.C299= | Silent (SNP) | VAF 190/726 reads (26%) | catalogued as rs201851669, COSV58673714; ClinVar: likely benign; called by muse, mutect2, varscan2
- ST8SIA3 | c.183A>C p.S61= | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- WDFY4 | c.3282G>T p.T1094= | Silent (SNP) | VAF 172/551 reads (31%) | called by muse, mutect2, varscan2
- AASS | c.*46G>T | 3'UTR (SNP) | VAF 42/197 reads (21%) | called by muse, mutect2, varscan2
- DPH2 | c.260+76C>T | Intron (SNP) | VAF 151/521 reads (29%) | catalogued as rs1557640236; called by muse, mutect2, varscan2
- H3C15 | chr1:149850230 C>T | 5'Flank (SNP) | VAF 68/194 reads (35%) | called by muse, varscan2
- HOXA2 | c.392-31G>A | Intron (SNP) | VAF 127/490 reads (26%) | called by muse, mutect2, varscan2
- LINC01630 | n.1201_1203del | RNA (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- MIR183 | n.106C>T | RNA (SNP) | VAF 82/320 reads (26%) | called by muse, mutect2, varscan2
- MIR512-2 | n.95C>A | RNA (SNP) | VAF 35/145 reads (24%) | called by mutect2, varscan2
- PDLIM3 | c.94-459C>T | Intron (SNP) | VAF 58/75 reads (77%) | called by muse, mutect2, varscan2
- RBM12B | c.-78+467C>T | Intron (SNP) | VAF 89/230 reads (39%) | catalogued as rs1295328235; called by muse, mutect2, varscan2
- SNW1 | c.774+969G>A | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- TFAP2A | c.-16C>A | 5'UTR (SNP) | VAF 101/737 reads (14%) | catalogued as COSV100116912; called by muse, varscan2
- TTC41P | n.407C>G | RNA (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2
